Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A3PK, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A3PK-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1:

RETROPERITONEAL SOFT TISSUE, MASS, RESECTION –
LOW GRADE MUCINOUS NEOPLASM INVOLVING FIBROADIPOSE TISSUE (see comment).

PART 2:

URETER, RIGHT DISTAL, BIOPSY –
BENIGN UROTHELIUM-COVERED TISSUE; NO TUMOR PRESENT.

PART 3:

URETER, LEFT DISTAL, BIOPSY –
BENIGN UROTHELIUM-COVERED TISSUE; NO TUMOR PRESENT.

PART 4:

URINARY BLADDER, RADICAL CYSTECTOMY –
A. INVASIVE UROTHELIAL CARCINOMA, HIGH-GRADE.
B. TUMOR MEASURES 4.7 CM IN GREATEST DIMENSION.
C. TUMOR INVADDES DETRUSOR MUSCLE (MUSCULARIS PROPRIA).
D. PERINEURAL INVASION AND ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
E. THE URETHRAL MARGIN SHOWS UROTHELIAL DYSPLASIA.
F. ALL OTHER RESECTION MARGINS ARE FREE OF TUMOR (see also parts 7 and 8).
G. BACKGROUND UROTHELIUM SHOWS ACUTE AND CHRONIC INFLAMMATION AND REACTIVE CHANGES.
H. PATHOLOGIC STAGE: pT2b N0 MX.

PART 5:

LYMPH NODES, RIGHT PELVIC, SELECTIVE DISSECTION-
THREE LYMPH NODES; NO TUMOR PRESENT (0/3).

PART 6:

SMALL BOWEL, RESECTION –
A. SEGMENTS OF SMALL BOWEL WITH ACUTE AND CHRONIC SEROSITIS, CONGESTION, ADHESIONS AND FOCAL ISCHEMIC-TYPE CHANGES.
B. RESECTION MARGINS ARE VIABLE-APPEARING.

PART 7:

URETER, RIGHT, MARGIN, BIOPSY –
BENIGN UROTHELIUM-COVERED TISSUE; NO TUMOR PRESENT.

PART 8:

URETER, LEFT, MARGIN, BIOPSY –
BENIGN UROTHELIUM-COVERED TISSUE WITH REACTIVE CHANGES; NO TUMOR PRESENT.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystectomy
TUMOR SITE: Posterior wall, Dome
TUMOR SIZE: Greatest dimension: 4.7 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Solid/nodule
PATHOLOGIC STAGING (pTNM): pT2b
pN0
Number of nodes examined: 3
pMX

MARGINS:

Margins uninvolved by invasive carcinoma

Margin: URETHRAL MARGIN WITH UROTHELIAL DYSPLASIA

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Absent

DIRECT EXTENSION OF INVASIVE TUMOR: None identified

ADDITIONAL PATHOLOGIC FINDINGS: Inflammation/regenerative changes

ICD-0-3
carcinoma, urothelial
812013
Coc site: bladder, posterior wall
C67.4
Path: bladder, NOS C67.9

Source: NCI Genomic Data Commons file 2b6dd4df-e802-4d69-9306-055efc574163 (TCGA-BT-A3PK.AD597E1C-BC15-46A3-9B7C-324250540B05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).